Somatic mutation profile of tumor specimen 0DTUIQ from CCDI case PBCHIF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.9 years (4,363 days).
Specimen 0DTUIQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1af6142-0f2f-449d-9b15-304568f73b17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUHY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/868dfbb6-9aa0-45cc-8b86-3570e1478b41

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 38/920 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2
- PCDHGA2 | c.2149C>T p.R717W | Missense Mutation (SNP) | VAF 33/670 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.03); catalogued as rs750116599, COSV53892669; called by muse, mutect2
- UNC5CL | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 56/473 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759752192; called by muse, mutect2, varscan2
- AAMP | c.879+7G>A | Splice Region (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- OR52E2 | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.041); called by muse, mutect2
- WDR97 | c.1106G>A p.G369D | Missense Mutation (SNP) | VAF 66/1096 reads (6%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNRNP35 | c.*41A>G | 3'UTR (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
